Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87H, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87H-01A (Primary Tumor).

[page 1 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-3

Adenocarcinoma of the prostate
8140/3

Site: Prostate NOS
061.9

11/21/13

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: M

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

PROSTATE, RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON GRADE 4+5, SCORE 9
- CARCINOMA INVOLVES ALL FOUR QUADRANTS OF THE PROSTATE GLAND, AND 50% OF THE SAMPLED PROSTATE
- EXTRAPROSTATIC EXTENSION BY CARCINOMA IDENTIFIED AT THE LEFT POSTERIOR BASE AND APEX, RIGHT POSTERIOR BASE, AND SOFT TISSUE NEAR LEFT SEMINAL VESICLE
- TUMOR PRESENT AT LEFT DISTAL APICAL (URETHRAL) MARGIN AND PERIPHERAL MARGINS IN THE LEFT POSTERIOR BASE, LEFT POSTERIOR APEX, RIGHT ANTERIOR BASE, AND ADJACENT TO LEFT AND RIGHT SEMINAL VESICLES
- TUMOR INVOLVES RIGHT AND LEFT SEMINAL VESICLES
- SEE SYNOPSIS REPORT

LYMPH NODE, RIGHT PELVIC, DISSECTION

- NO EVIDENCE OF MALIGNANCY IN SEVEN LYMPH NODES (0/7)

LYMPH NODE, LEFT PELVIC, DISSECTION (INCLUDING FS1A, B, AND C)

- NO EVIDENCE OF MALIGNANCY IN NINE LYMPH NODES (0/9)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pick-up 'left pelvic lymph nodes' consists of multiple pieces of yellow adipose tissue. Sectioned to show a 2.8 cm tan lymph node and a 1.4 cm fatty replaced lymph node. The tan lymph node is frozen as FS1A and FS1B. The fatty lymph node is frozen as FS1C. Rest for permanents."

"Brought to frozen 'prostate' consists of a 50 gram prostate measuring 4.5 cm from medial to lateral, 4.0 cm from anterior to posterior, and 3.5 cm from superior to inferior. Right seminal vesicle measures 4.8 x 1.5 x 0.5 cm. and left seminal vesicle measures 1.6 x 1.5 x 0.5 cm. Tissue taken for tumor bank," by

[page 2 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

FS1A: Left pelvic lymph nodes, biopsy
- "No evidence of malignancy," by

FS1B: Left pelvic lymph nodes, biopsy
- "No evidence of malignancy," by

FS1C: Left pelvic lymph node, biopsy
- "No evidence of malignancy," by

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

The patient is a [REDACTED] year old white man with serum prostate specific antigen of 7, has left lobe nodule, and Gleason grade 4 and 5 adenocarcinoma. Operative procedure: Not stated.

Specimen(s) Received:

A: LYMPH NODE, RIGHT PELVIC
B: LYMPH NODE, LEFT PELVIC
C: PROSTATE

Gross Description:

The specimen is received in three specimen containers, each labeled [REDACTED]. The first specimen container is labeled "right pelvic lymph nodes." It holds a disrupted portion of fatty tissue, containing palpable lymph nodes, measuring 5.9 x 2.6 x 1.1 cm. The lymph nodes are submitted in toto. Labeled A1 and A2 - bisected lymph nodes; A3 - remaining lymph nodes. Jar 1.

The second specimen container is labeled "left pelvic lymph nodes for frozen section" and "FS1A/B/C/X." It holds three tissue cassettes, labeled "FS1A," "FS1B," and "FS1C." They hold remnants of intraoperative frozen section measuring 2.2, 2.4, and 1.9 x 1.5 x 0.4 cm in aggregate, respectively. Submitted in cassette labeled B1, B2, B3, respectively. Additionally included in the specimen container are fatty tissue fragments measuring in aggregate 2.5 x 2.2 x 0.6 cm. Labeled B4. Jar 0.

The third specimen container is labeled "prostate." It holds a previously inked 50 gram prostate gland with the measurements conforming with those in the intraoperative consultation. In addition, the left and right vas deferentia measure 1.6 x 0.5 x 0.4 cm and 0.2 x 0.7 x 0.5 cm, respectively. They are left and right lateral defects, where tissue was taken for tumor bank, measure 2.2 x 0.4 cm and 2.6 x 0.5 cm. The urethra is probe patent. The bilateral seminal vesicles are grossly normal on cut surface. The cut sections disclose diffusely nodular posterior glands and spongy prostatic parenchyma at the periphery. Labeled C1 - shave bladder neck margin; C2 and C3 - left apical margin; C4 and C5 - right apical margin; C6 and C7 - left and right seminal vesicles; C8 to C11 - left posterior base; C12 and C14 - left posterior apex; C15 through C18 - right posterior base; C19 to C21 - right posterior apex; C22 and C23 - left anterior base; C24 and C25 - left anterior apex; C26 and C27 - right anterior base; C28 and C29 - right anterior apex. Jar 2.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

[page 3 of 5]
Patient Name: [REDACTED]

[REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent = 50% of prostate gland involved by carcinoma

GLEASON'S GRADE

The Gleason's Grade is 4+5, score 9

TUMOR LOCATION

The location of the tumor is the

- right base
- right apex
- left base
- left apex

PERINEURAL INVASION

Perineural invasion is identified

VASCULAR INVASION

Vascular invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is established

The tumor extends into the periprostatic soft tissues in multiple sites (see diagnosis)

SEMINAL VESICLES

The tumor extends into the right seminal vesicle wall

The tumor extends into the left seminal vesicle wall

The tumor involves perivesicular soft tissue

SAMPLED SPECIMEN MARGINS

Tumor is present at sampled distal apical (urethral) margin of resection

Tumor is present at sampled peripheral margin of resection in the multiple sites (see diagnosis)

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade, focal

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Right pelvic: 0/7

Left pelvic: 0/9

Extranodal extension by tumor is not applicable; no nodal metastases are present

PRIMARY TUMOR (T)

Tumor invades seminal vesicle(s) (T3b)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis (N0)

DISTANT METASTASIS

No distant metastasis (M0)

STAGE GROUPING

Based on this information, the overall AJCC/UICC stage of the tumor is T3/N0/M0/Gleason score 9 (Stage III)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Surgical Pathology report is available on-line on

[page 4 of 5]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

[REDACTED] SURGICAL PATHOLOGY REPORT [REDACTED]

	Yes	No
Metastatic Malignancy History		
Metastatic/Synchronous Primary Malignancy		

END OF REPORT

Page 4 of 4

[page 5 of 5]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica) _____ Completed Date _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason score on the initial pathology report is $4+5=9$	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Top slide review Gleason score is $4+3=7$	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	The top slide review showed a different Gleason score from the Gleason score on the initial Pathology Report.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewer

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file e333a9e9-d7f8-4b54-a329-6bcd7d08ad3d (TCGA-VP-A87H.B2B58670-AE26-43A0-8D3C-AAF354958727.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).